Gene-level copy-number profile of tumor specimen HCM-CSHL-0247-C18-01A from HCMI case HCM-CSHL-0247-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 76.5 years (27,936 days).
Specimen HCM-CSHL-0247-C18-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e450c089-05c1-4203-a13a-b111b0a4537a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0247-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/72118ea7-6e7d-4d12-b597-e6095555d5a3

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 117; copy number 2: 13,753; copy number 3: 7,032; copy number 4: 30,767; copy number 5: 2,757; copy number 6: 2,625; copy number 7: 833; copy number 9: 470; copy number 10: 26.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:7,200,756–7,247,571, 3 genes: AF228730.1, AF228730.3, OR7E125P.
- chr17:18,426,861–18,442,895, 2 genes: KRT17P2, KRT16P1.
- chr17:18,452,955–18,453,739, 2 genes (within-gene range 0–1): AL353997.1, AL353997.4.
- chr17:18,497,095–18,551,705, 4 genes (within-gene range 0–4): NOS2P2, FAM106A, USP32P2, SRP68P2.
- chr19:43,153,279–43,269,530, 5 genes: AC005392.1, PSG5, PSG4, CEACAMP10, PSG9.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 496 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:18,467,172–44,256,596, 496 genes, copy number 9–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 113. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
